Somatic mutation profile of tumor specimen MP2PRT-PAVFZA-TMP1-A (aliquot MP2PRT-PAVFZA-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVFZA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,714 days).
Specimen MP2PRT-PAVFZA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7782bc1-15c0-4296-80dc-f7a0d406b17c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFZA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFZA-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/737dbe54-b9c2-4f3c-aceb-2e6e5167e4a3

The open-access MAF lists 185 somatic variants for this specimen: 139 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 39, Nonsense Mutation 14, Intron 4, 3'UTR 1, Splice Region 1, Splice Site 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 221/502 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587777177, CM140924, COSV99301371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 127/345 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.3019C>T p.L1007F | Missense Mutation (SNP) | VAF 175/411 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs1373211811; called by muse, mutect2, varscan2
- ASTE1 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 16/458 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as COSV99393992; called by muse, mutect2
- CCDC88A | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99711026; called by muse, mutect2, varscan2
- CDH23 | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 53/590 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs768452198, COSV56446591; ClinVar: uncertain significance; called by muse, mutect2
- CDKL2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 104/204 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100277084, COSV56733967; called by muse, mutect2, varscan2
- CIAPIN1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 135/265 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.269); catalogued as COSV67953304; called by muse, mutect2, varscan2
- COL19A1 | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs150270870; called by muse, mutect2, varscan2
- CTCF | c.1702-1G>C p.X568_splice | Splice Site (SNP) | VAF 132/259 reads (51%) | catalogued as COSV50461368; called by muse, mutect2, varscan2
- CXADR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV53027998; called by muse, mutect2, varscan2
- DOCK1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54737181; called by muse, mutect2, varscan2
- DSG1 | c.2119G>C p.D707H | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766178255; called by muse, mutect2, varscan2
- EFCAB8 | c.3599C>G p.S1200C | Missense Mutation (SNP) | VAF 240/574 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.843); catalogued as rs1289567308; called by muse, mutect2
- ELF4 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57452624; called by muse, mutect2
- EP400 | c.2078C>G p.S693* | Nonsense Mutation (SNP) | VAF 302/593 reads (51%) | catalogued as COSV100200450; called by muse, mutect2, varscan2
- EYS | c.4452G>A p.W1484* | Nonsense Mutation (SNP) | VAF 121/256 reads (47%) | catalogued as rs1428994453; called by muse, mutect2, varscan2
- FGF16 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 168/217 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV101466316, COSV71546210; called by muse, mutect2, varscan2
- FMN2 | c.2908C>G p.L970V | Missense Mutation (SNP) | VAF 149/388 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); catalogued as COSV60434260; called by muse, varscan2
- GABRR3 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 109/196 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV72084115; called by muse, mutect2, varscan2
- GRIN2B | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 215/290 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs199941557, COSV74206507; called by muse, mutect2, varscan2
- GRK4 | c.590G>C p.G197A (on ENST00000398052 / NM_182982.3; = p.G165A on NM_005307.3) | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61668151; called by muse, varscan2
- H2BC11 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 170/365 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV100345616, COSV60362089, COSV60362099; called by muse, mutect2, varscan2
- HIVEP1 | c.2258C>G p.S753* | Nonsense Mutation (SNP) | VAF 155/356 reads (44%) | catalogued as COSV101045412; called by muse, mutect2, varscan2
- ITPKB | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 185/413 reads (45%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs1048888287; called by muse, mutect2, varscan2
- KRT37 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 202/440 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1183641258, COSV56656687; called by muse, mutect2, varscan2
- NEK5 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 176/357 reads (49%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV100839227; called by muse, mutect2, varscan2
- NR1H4 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV51855969; called by muse, mutect2, varscan2
- NR5A1 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 152/344 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs150382425; called by muse, mutect2, varscan2
- NRXN3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 259/516 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs779834039; called by muse, mutect2, varscan2
- OR8J1 | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57319562; called by muse, mutect2, varscan2
- PDE8A | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 184/470 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.18); catalogued as rs1289041095, COSV59634980; called by muse, mutect2, varscan2
- PIK3R3 | c.999G>C p.K333N | Missense Mutation (SNP) | VAF 183/391 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53111866; called by muse, mutect2, varscan2
- PRG4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 402/1008 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs565219311; called by muse, varscan2
- PRKAG2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1318843859; called by muse, mutect2, varscan2
- RASGRP1 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV60365924; called by muse, mutect2, varscan2
- RBSN | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 122/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456941640, COSV53791297; called by muse, mutect2, varscan2
- SCN7A | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 148/345 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.492); catalogued as rs761616505; called by muse, mutect2, varscan2
- SHROOM4 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 133/144 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV56785956; called by muse, mutect2, varscan2
- SPAG6 | c.1215G>C p.K405N | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100510548, COSV57618584; called by muse, mutect2
- SPATA2L | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 243/506 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1470163866; called by muse, mutect2, varscan2
- SRCAP | c.6662C>G p.S2221C | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs756686784, COSV52682733; called by muse, mutect2, varscan2
- TERF1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 179/385 reads (46%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.051); catalogued as rs1460074735; called by muse, mutect2, varscan2
- TEX26 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100993998; called by muse, mutect2, varscan2
- TFEC | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55397698; called by muse, mutect2, varscan2
- TNN | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 233/503 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs756217445; called by muse, mutect2, varscan2
- WNT10A | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 308/658 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.262); catalogued as rs1188846817; called by muse, mutect2, varscan2
- YEATS2 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs747643488; called by muse, mutect2, varscan2
- ZBTB41 | c.112C>G p.H38D | Missense Mutation (SNP) | VAF 172/322 reads (53%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV66359003; called by muse, mutect2, varscan2
- ZNF644 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 149/361 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61348375; called by muse, mutect2, varscan2
- ABCB4 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 169/393 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ABHD17B | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 110/226 reads (49%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.4709C>A p.A1570D | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ADGB | c.4048C>G p.H1350D | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AFF4 | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- AKR1C4 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 194/413 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ANKRD18A | c.837G>C p.L279F | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.587); called by muse, mutect2
- AP2A2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 267/680 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASXL3 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ATP6V0D1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 183/419 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- BOD1L1 | c.6604G>T p.E2202* | Nonsense Mutation (SNP) | VAF 164/352 reads (47%) | called by muse, mutect2, varscan2
- C10orf88 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- C12orf29 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 84/182 reads (46%) | called by muse, mutect2, varscan2
- CC2D2A | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- COL18A1 | c.1993G>T p.D665Y (on ENST00000359759 / NM_130444.3; = p.D430Y on NM_030582.4) | Missense Mutation (SNP) | VAF 169/422 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSTF3 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CUBN | c.8614G>C p.E2872Q | Missense Mutation (SNP) | VAF 158/316 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CYP11B2 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 290/655 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DIPK1A | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DMP1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1A | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ESM1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ESPN | c.4072G>C p.E1358Q | Missense Mutation (SNP) | VAF 123/291 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FIG4 | c.2615C>G p.S872C | Missense Mutation (SNP) | VAF 156/380 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FOXO1 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 241/537 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FZD5 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 275/634 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GALNT1 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 56/120 reads (47%) | called by muse, varscan2
- GNG8 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 34/495 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2
- GSTA3 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IGDCC4 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- KALRN | c.5618C>T p.A1873V (on ENST00000360013 / NM_001024660.4; = p.A176V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KRTAP10-11 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 192/566 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LAMA2 | c.8693G>C p.R2898T | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAPTM5 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- LCE5A | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 298/620 reads (48%) | called by muse, mutect2, varscan2
- LMOD2 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 154/358 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LRIT1 | c.1691C>G p.S564C | Missense Mutation (SNP) | VAF 211/455 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MAPK8IP3 | c.600G>C p.R200= | Splice Region (SNP) | VAF 132/255 reads (52%) | called by muse, mutect2, varscan2
- MED1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- METTL7B | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MRGPRX1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 195/1105 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MTR | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 167/406 reads (41%) | called by muse, mutect2, varscan2
- MUC2 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 262/533 reads (49%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.3660C>G p.C1220W | Missense Mutation (SNP) | VAF 183/422 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NUDCD2 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NUP153 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 165/325 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NYNRIN | c.4997A>T p.H1666L | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- OR2AJ1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 150/334 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCDH1 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 202/468 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDH11X | c.2948C>G p.S983* | Nonsense Mutation (SNP) | VAF 333/353 reads (94%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 228/499 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PEX5 | c.1075G>C p.E359Q (on ENST00000420616; = p.E351Q on NM_000319.5) | Missense Mutation (SNP) | VAF 147/317 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIEZO2 | c.6653C>A p.A2218E | Missense Mutation (SNP) | VAF 114/301 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- POLR2B | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPH2 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RNF212 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 211/421 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RPS5 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 169/366 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SALL1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- SCCPDH | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 106/189 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SIPA1L3 | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 167/370 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC10A4 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC17A6 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 111/233 reads (48%) | called by muse, mutect2, varscan2
- SLC26A1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 258/573 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ST3GAL2 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 180/348 reads (52%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUMF1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, varscan2
- TBC1D4 | c.1746G>C p.M582I | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TDRD6 | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 163/335 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- THAP7 | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 214/444 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.4823G>A p.G1608E | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPGS2 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM2 | c.1951C>G p.Q651E (on ENST00000437508; = p.Q678E on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM63 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 202/480 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TRPM6 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TSPAN33 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 162/381 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TTN | c.66403G>C p.E22135Q (on ENST00000591111; = p.E14711Q on NM_003319.4) | Missense Mutation (SNP) | VAF 164/416 reads (39%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBA2 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 144/332 reads (43%) | called by muse, mutect2, varscan2
- UBR4 | c.4630C>G p.L1544V | Missense Mutation (SNP) | VAF 163/377 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UCMA | c.330G>C p.E110D | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USF3 | c.4853C>G p.S1618C | Missense Mutation (SNP) | VAF 171/359 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 128/317 reads (40%) | called by muse, mutect2, varscan2
- ZFHX3 | c.4831C>G p.L1611V | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP28 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2, varscan2
- ZNF101 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ZNF200 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZNF224 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF300 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 168/375 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ZNF462 | c.6929C>G p.S2310C | Missense Mutation (SNP) | VAF 168/378 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF587 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 186/382 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF746 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 103/733 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- ACVR2B | c.24C>T p.L8= | Silent (SNP) | VAF 149/352 reads (42%) | called by muse, mutect2, varscan2
- AKR7L | c.546C>T p.L182= | Silent (SNP) | VAF 150/351 reads (43%) | called by muse, mutect2, varscan2
- AOC1 | c.216C>T p.I72= | Silent (SNP) | VAF 200/419 reads (48%) | catalogued as rs767444736, COSV62870747; called by muse, mutect2, varscan2
- ATP5PB | c.381C>T p.L127= | Silent (SNP) | VAF 115/236 reads (49%) | called by muse, mutect2, varscan2
- AXL | c.1899C>G p.L633= (on ENST00000301178 / NM_021913.5; = p.L624= on NM_001699.6) | Silent (SNP) | VAF 183/387 reads (47%) | called by muse, mutect2, varscan2
- CCKAR | c.312C>G p.L104= | Silent (SNP) | VAF 206/457 reads (45%) | called by muse, mutect2, varscan2
- CCNA2 | c.174G>A p.P58= | Silent (SNP) | VAF 274/570 reads (48%) | called by muse, mutect2, varscan2
- CD36 | c.954C>T p.I318= | Silent (SNP) | VAF 94/219 reads (43%) | called by muse, mutect2, varscan2
- CPN2 | c.1164C>T p.F388= | Silent (SNP) | VAF 192/410 reads (47%) | catalogued as rs1560282463; called by muse, mutect2, varscan2
- CSMD1 | c.399C>T p.F133= | Silent (SNP) | VAF 65/172 reads (38%) | called by muse, mutect2, varscan2
- CTCF | c.1548C>A p.T516= | Silent (SNP) | VAF 165/355 reads (46%) | catalogued as COSV50462325; called by muse, mutect2, varscan2
- EIF5B | c.3639G>C p.L1213= | Silent (SNP) | VAF 11/298 reads (4%) | called by muse, mutect2
- FANCA | c.2052G>A p.L684= | Silent (SNP) | VAF 33/476 reads (7%) | called by muse, mutect2
- FOXC2 | c.1146C>G p.L382= | Silent (SNP) | VAF 247/560 reads (44%) | called by muse, mutect2, varscan2
- GABARAPL1 | c.353G>A p.*118= | Silent (SNP) | VAF 82/93 reads (88%) | catalogued as rs770747565; called by muse, mutect2, varscan2
- GID4 | c.312C>G p.L104= | Silent (SNP) | VAF 360/403 reads (89%) | called by muse, mutect2, varscan2
- GSE1 | c.1770G>C p.L590= | Silent (SNP) | VAF 281/629 reads (45%) | catalogued as rs756012496; called by muse, mutect2, varscan2
- HMCN1 | c.14850C>T p.L4950= | Silent (SNP) | VAF 111/345 reads (32%) | catalogued as COSV54936716, COSV54945305; called by muse, mutect2, varscan2
- HRH1 | c.993C>G p.L331= | Silent (SNP) | VAF 143/343 reads (42%) | catalogued as COSV67954949; called by muse, mutect2, varscan2
- IGKV1D-8 | chr2:90221383 del CCCACAGTGTTA | Silent (DEL) | VAF 55/104 reads (53%) | called by pindel, varscan2
- IGSF10 | c.5421C>G p.L1807= | Silent (SNP) | VAF 228/499 reads (46%) | called by muse, mutect2, varscan2
- KCNE4 | c.279C>T p.V93= | Silent (SNP) | VAF 230/511 reads (45%) | catalogued as COSV99919164; called by muse, mutect2, varscan2
- LMNTD2 | c.1308G>C p.S436= | Silent (SNP) | VAF 240/487 reads (49%) | catalogued as rs1170486526; called by muse, mutect2, varscan2
- LRP1 | c.9087G>A p.P3029= | Silent (SNP) | VAF 163/357 reads (46%) | catalogued as rs200528840; called by muse, mutect2, varscan2
- MYO15A | c.9906C>G p.L3302= | Silent (SNP) | VAF 208/237 reads (88%) | called by muse, mutect2, varscan2
- MYO1F | c.2637G>A p.V879= | Silent (SNP) | VAF 206/470 reads (44%) | catalogued as rs754744275, COSV57800744; called by muse, mutect2, varscan2
- MYOM1 | c.2058G>C p.V686= | Silent (SNP) | VAF 167/384 reads (43%) | called by muse, mutect2
- NIFK | c.438G>A p.V146= | Silent (SNP) | VAF 189/411 reads (46%) | called by muse, mutect2, varscan2
- OPN1SW | c.672G>A p.L224= | Silent (SNP) | VAF 119/266 reads (45%) | catalogued as COSV50823361; called by muse, mutect2, varscan2
- PCDH17 | c.729C>T p.F243= | Silent (SNP) | VAF 178/398 reads (45%) | catalogued as COSV64980306; called by muse, mutect2, varscan2
- PCDHB4 | c.2055C>G p.L685= | Silent (SNP) | VAF 402/799 reads (50%) | called by muse, mutect2, varscan2
- PDK1 | c.72C>T p.F24= | Silent (SNP) | VAF 253/562 reads (45%) | catalogued as rs1051781294; called by muse, varscan2
- SF3A3 | c.657G>A p.K219= | Silent (SNP) | VAF 128/315 reads (41%) | called by muse, mutect2, varscan2
- SF3B1 | c.2604G>A p.V868= | Silent (SNP) | VAF 118/349 reads (34%) | called by muse, mutect2, varscan2
- SIM1 | c.250C>T p.L84= | Silent (SNP) | VAF 14/556 reads (3%) | called by muse, mutect2
- SLC39A5 | c.894C>T p.L298= | Silent (SNP) | VAF 205/482 reads (43%) | called by muse, mutect2, varscan2
- TANGO6 | c.2601G>A p.Q867= | Silent (SNP) | VAF 131/299 reads (44%) | catalogued as COSV55763720; called by muse, mutect2, varscan2
- TNFRSF19 | c.1242C>G p.L414= | Silent (SNP) | VAF 138/289 reads (48%) | catalogued as COSV50323011; called by muse, mutect2, varscan2
- USH1G | c.135C>G p.L45= | Silent (SNP) | VAF 178/409 reads (44%) | catalogued as rs929326559; called by muse, mutect2, varscan2
- CA6 | c.259+2103G>C | Intron (SNP) | VAF 139/367 reads (38%) | called by muse, mutect2, varscan2
- GTDC1 | c.179+31406G>C | Intron (SNP) | VAF 167/378 reads (44%) | called by muse, mutect2, varscan2
- KRAS | c.*22C>A | 3'UTR (SNP) | VAF 21/27 reads (78%) | catalogued as CM070970, COSV55666258, COSV56095155; called by muse, mutect2, varscan2
- MEIS3 | c.13-301C>G | Intron (SNP) | VAF 165/399 reads (41%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81168093 G>A | 3'Flank (SNP) | VAF 136/284 reads (48%) | called by muse, mutect2, varscan2
- PLCXD1 | c.-1G>A | 5'UTR (SNP) | VAF 158/349 reads (45%) | catalogued as COSV101087974; called by muse, mutect2, varscan2
- SMIM27 | c.45+402G>C | Intron (SNP) | VAF 127/312 reads (41%) | called by muse, mutect2, varscan2
